Gene-level copy-number profile of tumor specimen HCM-BROD-0613-C71-01A from HCMI case HCM-BROD-0613-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.0 years (18,640 days).
Specimen HCM-BROD-0613-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file faa30944-5e78-4bcc-9b6d-45e889013bf1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0613-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/edce3bf1-59b4-41e3-b899-24963f31d3eb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 18; copy number 2: 8,600; copy number 3: 377; copy number 4: 38,221; copy number 5: 114; copy number 6: 10,023; copy number 7: 1; copy number 8: 1,366; copy number 10: 102; copy number 28: 6; copy number 68: 13; copy number 70: 4; copy number 113: 56.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:52,452–118,204, 5 genes: AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4.
- chr17:18,426,861–18,475,920, 6 genes (within-gene range 0–3): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 181 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,668,684–16,666,331, 23 genes, copy number 28–70: AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA.
- chr6:69,866,556–75,919,537, 102 genes, copy number 10 (broad region; genes not listed).
- chr12:57,431,116–58,813,060, 56 genes, copy number 113: AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
